Somatic mutation profile of tumor specimen TARGET-10-PARBDP-09A (aliquot TARGET-10-PARBDP-09A-01D) from TARGET case TARGET-10-PARBDP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,411 days).
Specimen TARGET-10-PARBDP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3d1d377-7b21-4236-abc5-3d1a60c76e1e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARBDP-10A (Blood Derived Normal), aliquot TARGET-10-PARBDP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a41bf47-6deb-4b53-9719-803fbe8c6854

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 1, Frame Shift Del 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2047A>G p.R683G | Missense Mutation (SNP) | VAF 38/40 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519721, COSV67572554, COSV67587550; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- BCAM | c.1738C>T p.R580C | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs376176106; called by muse, mutect2, varscan2
- GRIN2B | c.190G>A p.V64M | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as rs150070901; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- HAS2 | c.116C>T p.T39M | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.899); catalogued as rs774095555, COSV58264099; called by muse, mutect2, varscan2
- LRFN5 | c.1289C>T p.T430M | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs571352632, COSV53270382; called by muse, mutect2, varscan2
- MGAM2 | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 60/103 reads (58%) | SIFT tolerated (0.7); PolyPhen benign (0.013); catalogued as rs1030566725, COSV72176497; called by muse, mutect2, varscan2
- ONECUT2 | c.1257_1260del p.N419Kfs*56 | Frame Shift Del (DEL) | VAF 40/97 reads (41%) | catalogued as rs1436303727; called by pindel, varscan2
- PRODH2 | c.907-8G>A | Splice Region (SNP) | VAF 5/13 reads (38%) | catalogued as rs923013604; called by muse, mutect2
- ATP13A1 | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- CEP350 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- MAGI1 | c.4085G>A p.R1362K | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRPM2 | c.1034C>T p.T345I | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, varscan2
- ASB15 | c.741G>A p.L247= | Silent (SNP) | VAF 28/51 reads (55%) | called by muse, mutect2, varscan2
- TTC3P1 | n.4992C>A | RNA (SNP) | VAF 35/87 reads (40%) | called by muse, mutect2, varscan2
